Somatic mutation profile of cancer-model specimen HCM-BROD-0564-C71-85R (3D Neurosphere, passage 4; aliquot HCM-BROD-0564-C71-85R-01D-A79L-36), derived from the recurrence tumor of HCMI case HCM-BROD-0564-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 65.5 years (23,928 days).
Specimen HCM-BROD-0564-C71-85R: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: 3D Neurosphere; Preservation method: Frozen; Passage count: 4.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a66c80ec-a0b9-4c12-8d88-732fc0865f47.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0564-C71-10A (Blood Derived Normal), aliquot HCM-BROD-0564-C71-10A-01D-A79L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d8aa8f78-8869-4c62-af90-db0c682e62f0

The open-access MAF lists 175 somatic variants for this specimen: 131 protein-altering or splice-affecting, 39 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 113, Silent 39, Nonsense Mutation 6, In Frame Del 3, Frame Shift Del 3, Intron 2, Splice Site 2, Splice Region 2, Frame Shift Ins 2, 5'Flank 1, RNA 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BBS9 | c.727G>A p.E243K | Missense Mutation (SNP) | VAF 104/402 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1562917450; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 201/405 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.733G>A p.G245S | Missense Mutation (SNP) | VAF 154/356 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs28934575, CM010463, CM900210, CM920674, COSV52661744, COSV52661877, COSV52713951, COSV52839866; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABO | c.931C>T p.R311C | Missense Mutation (SNP) | VAF 251/544 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as rs781834957; called by muse, mutect2, varscan2
- AGAP3 | c.2350G>A p.G784R (on ENST00000622464; = p.G820R on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 184/566 reads (33%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.911); catalogued as rs1185964420; called by muse, varscan2
- ATP2A3 | c.3051G>A p.W1017* | Nonsense Mutation (SNP) | VAF 139/285 reads (49%) | catalogued as COSV59229502; called by muse, mutect2, varscan2
- CACNG5 | c.197-1G>A p.X66_splice | Splice Site (SNP) | VAF 132/260 reads (51%) | catalogued as rs1158433950; called by muse, mutect2, varscan2
- CD8B | c.280C>T p.R94W | Missense Mutation (SNP) | VAF 198/434 reads (46%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.91); catalogued as rs747895168, COSV58924933; called by muse, mutect2, varscan2
- CDH4 | c.784G>A p.D262N | Missense Mutation (SNP) | VAF 48/334 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.083); catalogued as COSV100848540, COSV100849420; called by muse, mutect2, varscan2
- CELF4 | c.607G>T p.A203S | Missense Mutation (SNP) | VAF 235/481 reads (49%) | SIFT tolerated (0.22); PolyPhen benign (0.238); catalogued as COSV58467987; called by muse, mutect2, varscan2
- COL24A1 | c.2765C>T p.P922L | Missense Mutation (SNP) | VAF 106/250 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.313); catalogued as COSV65310594; called by muse, mutect2, varscan2
- CSMD1 | c.347C>G p.S116C | Missense Mutation (SNP) | VAF 74/141 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs760230512, COSV68248557; called by muse, varscan2
- DISP3 | c.1936G>C p.D646H | Missense Mutation (SNP) | VAF 208/407 reads (51%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.863); catalogued as COSV53831706; called by muse, mutect2, varscan2
- DOCK5 | c.168G>C p.K56N | Missense Mutation (SNP) | VAF 88/223 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.901); catalogued as COSV52411138; called by muse, mutect2, varscan2
- DPF1 | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 19/296 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.534); catalogued as rs1357176953; called by muse, mutect2
- EBF1 | c.821C>T p.T274M | Missense Mutation (SNP) | VAF 144/242 reads (60%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs755362001, COSV58177645; called by muse, mutect2, varscan2
- FBH1 | c.3008C>T p.A1003V (on ENST00000362091 / NM_178150.3; = p.A1054V on NM_032807.4) | Missense Mutation (SNP) | VAF 69/433 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs749762089; called by muse, mutect2, varscan2
- FGD5 | c.1297G>A p.G433R | Missense Mutation (SNP) | VAF 244/394 reads (62%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV53242100; called by muse, mutect2, varscan2
- FTMT | c.79G>A p.A27T | Missense Mutation (SNP) | VAF 267/269 reads (99%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as rs1268012673, COSV58419632; called by muse, mutect2, varscan2
- GRAP2 | c.769A>T p.M257L | Missense Mutation (SNP) | VAF 48/296 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0.444); catalogued as COSV100703231, COSV59995476; called by muse, mutect2, varscan2
- GYPC | c.160C>T p.P54S | Missense Mutation (SNP) | VAF 52/302 reads (17%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs1465402454, COSV52146059; called by muse, mutect2, varscan2
- HECW1 | c.3763C>T p.R1255C | Missense Mutation (SNP) | VAF 73/301 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV67825458, COSV67829709; called by muse, mutect2, varscan2
- HEYL | c.38A>C p.E13A | Missense Mutation (SNP) | VAF 88/425 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.271); catalogued as COSV100865352; called by muse, mutect2, varscan2
- IL10RA | c.289C>T p.R97W | Missense Mutation (SNP) | VAF 223/464 reads (48%) | SIFT tolerated (0.24); PolyPhen benign (0.099); catalogued as rs374330101; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LAMB3 | c.937T>C p.C313R | Missense Mutation (SNP) | VAF 123/239 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV61917017; called by muse, mutect2, varscan2
- MAGI1 | c.4352G>C p.R1451P | Missense Mutation (SNP) | VAF 153/226 reads (68%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.899); catalogued as COSV58314128; called by muse, mutect2, varscan2
- MIPEP | c.1253G>A p.R418Q | Missense Mutation (SNP) | VAF 85/171 reads (50%) | SIFT tolerated (0.33); PolyPhen benign (0.121); catalogued as rs780546470; called by muse, mutect2, varscan2
- MISP | c.287G>A p.R96H | Missense Mutation (SNP) | VAF 249/492 reads (51%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs552717754, COSV53119336; called by muse, mutect2, varscan2
- MMP17 | c.191C>T p.P64L | Missense Mutation (SNP) | VAF 191/343 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); catalogued as rs1043956817; called by muse, mutect2, varscan2
- MPDZ | c.5632G>A p.A1878T (on ENST00000319217 / NM_001330637.2; = p.A1849T on NM_003829.5) | Missense Mutation (SNP) | VAF 89/89 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763671820, COSV100056480; called by muse, mutect2, varscan2
- MROH2A | c.2908G>A p.V970M | Missense Mutation (SNP) | VAF 238/351 reads (68%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs576717420; called by muse, mutect2, varscan2
- NBAS | c.4001G>A p.R1334H | Missense Mutation (SNP) | VAF 184/347 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs140188229; called by muse, mutect2, varscan2
- NKRF | c.167G>A p.R56H | Missense Mutation (SNP) | VAF 218/454 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.761); catalogued as rs747350527, COSV58661864; called by muse, mutect2, varscan2
- OLFML2B | c.665T>C p.M222T | Missense Mutation (SNP) | VAF 207/447 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as rs1033126448; called by muse, mutect2, varscan2
- OR5AS1 | c.634G>T p.V212L | Missense Mutation (SNP) | VAF 168/347 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV57982118; called by muse, mutect2, varscan2
- OR5V1 | c.703C>T p.R235* | Nonsense Mutation (SNP) | VAF 138/271 reads (51%) | catalogued as rs148190376; called by muse, mutect2, varscan2
- PARVB | c.14C>T p.P5L | Missense Mutation (SNP) | VAF 122/231 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV58687053; called by muse, mutect2, varscan2
- PCNX1 | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 101/272 reads (37%) | catalogued as rs1366185598; called by muse, mutect2, varscan2
- PLIN5 | c.1186G>A p.V396M | Missense Mutation (SNP) | VAF 325/564 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101113622, COSV67850684; called by muse, mutect2, varscan2
- PPAN-P2RY11 | c.1873T>C p.Y625H | Missense Mutation (SNP) | VAF 157/477 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1452634728; called by muse, mutect2, varscan2
- PSG5 | c.603C>G p.I201M | Missense Mutation (SNP) | VAF 113/476 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.145); catalogued as COSV61655122; called by muse, mutect2
- PSPC1 | c.1331G>A p.G444E | Missense Mutation (SNP) | VAF 94/343 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.376); catalogued as rs535273248, COSV100142367; called by muse, mutect2, varscan2
- SCN2A | c.1748G>A p.R583Q | Missense Mutation (SNP) | VAF 49/303 reads (16%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.653); catalogued as rs1158928024, COSV51842974; called by muse, mutect2, varscan2
- SOCS3 | c.347G>A p.R116H | Missense Mutation (SNP) | VAF 291/594 reads (49%) | SIFT tolerated (0.2); PolyPhen benign (0.02); catalogued as COSV58271302; called by muse, mutect2, varscan2
- SOWAHD | c.710G>A p.R237Q | Missense Mutation (SNP) | VAF 303/587 reads (52%) | SIFT deleterious (0.05); PolyPhen benign (0.186); catalogued as rs1298166059; called by muse, mutect2, varscan2
- STT3A | c.1310G>A p.R437H | Missense Mutation (SNP) | VAF 131/262 reads (50%) | SIFT tolerated (0.18); PolyPhen benign (0.026); catalogued as rs776079118, COSV67064209; called by muse, mutect2, varscan2
- TM6SF2 | c.644G>T p.R215L | Missense Mutation (SNP) | VAF 64/335 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs750038678, COSV66984945; called by muse, mutect2, varscan2
- TPH1 | c.791A>G p.Y264C | Missense Mutation (SNP) | VAF 104/191 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs375116786; called by muse, mutect2, varscan2
- ZNF90 | c.1439T>C p.L480P | Missense Mutation (SNP) | VAF 18/344 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs782782063; called by muse, mutect2
- AC073111.3 | c.529C>T p.R177C | Missense Mutation (SNP) | VAF 293/833 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.041); called by muse, varscan2
- ACACA | c.1829A>G p.N610S | Missense Mutation (SNP) | VAF 60/275 reads (22%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- AJUBA | c.1559G>A p.C520Y | Missense Mutation (SNP) | VAF 162/274 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AL136295.1 | c.1165T>C p.S389P | Missense Mutation (SNP) | VAF 16/358 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.943); called by muse, mutect2
- ARSD | c.496dup p.L166Pfs*6 | Frame Shift Ins (INS) | VAF 269/694 reads (39%) | called by mutect2, pindel, varscan2
- ASCC3 | c.4910A>G p.N1637S | Missense Mutation (SNP) | VAF 23/203 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.347); called by muse, mutect2, varscan2
- ATP7B | c.1759A>C p.T587P | Missense Mutation (SNP) | VAF 71/344 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- C3orf33 | c.367C>T p.L123F (on ENST00000340171 / NM_001308229.2; = p.L80F on NM_173657.2) | Missense Mutation (SNP) | VAF 93/255 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CACNB3 | c.1387G>A p.D463N | Missense Mutation (SNP) | VAF 225/471 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CCDC69 | c.442A>G p.M148V | Missense Mutation (SNP) | VAF 142/142 reads (100%) | SIFT deleterious (0.03); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- CCNF | c.878T>C p.V293A | Missense Mutation (SNP) | VAF 13/361 reads (4%) | SIFT tolerated (0.54); PolyPhen benign (0.003); called by muse, mutect2
- CD22 | c.707T>A p.L236Q | Missense Mutation (SNP) | VAF 42/201 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDK14 | c.167A>G p.D56G (on ENST00000380050 / NM_001287135.2; = p.D38G on NM_012395.3) | Missense Mutation (SNP) | VAF 56/427 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- CHD9 | c.506A>G p.E169G | Missense Mutation (SNP) | VAF 89/337 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.537); called by muse, mutect2, varscan2
- CHD9 | c.3752G>A p.R1251K | Missense Mutation (SNP) | VAF 173/263 reads (66%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- CHMP1A | c.458T>C p.I153T | Missense Mutation (SNP) | VAF 124/369 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- CLN3 | c.1118C>T p.A373V (on ENST00000360019 / NM_001286104.2; = p.A397V on NM_000086.2) | Missense Mutation (SNP) | VAF 152/240 reads (63%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- CPXCR1 | c.868G>A p.E290K | Missense Mutation (SNP) | VAF 132/278 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- CYP27B1 | c.215T>A p.F72Y | Missense Mutation (SNP) | VAF 109/548 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CYP2A7 | c.681G>C p.M227I | Missense Mutation (SNP) | VAF 16/311 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.242); called by muse, mutect2
- CYSTM1 | c.280G>A p.D94N | Missense Mutation (SNP) | VAF 122/124 reads (98%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DNHD1 | c.8261_8280del p.G2754Efs*20 | Frame Shift Del (DEL) | VAF 134/365 reads (37%) | called by mutect2, pindel, varscan2
- DOCK7 | c.5971A>G p.T1991A (on ENST00000635253 / NM_001367561.1; = p.T1960A on NM_033407.3) | Missense Mutation (SNP) | VAF 32/201 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.215); called by muse, mutect2, varscan2
- FAF1 | c.160A>T p.S54C | Missense Mutation (SNP) | VAF 105/208 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FLNA | c.452C>T p.S151F | Missense Mutation (SNP) | VAF 70/388 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); called by muse, mutect2, varscan2
- FN1 | c.6825C>G p.S2275R (on ENST00000359671 / NM_001365524.2; = p.S2244R on NM_002026.4) | Missense Mutation (SNP) | VAF 117/296 reads (40%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FNBP4 | c.1516G>A p.E506K | Missense Mutation (SNP) | VAF 40/240 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- GPR101 | c.151G>A p.V51M | Missense Mutation (SNP) | VAF 221/523 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- HES1 | c.83C>A p.P28Q | Missense Mutation (SNP) | VAF 100/349 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- HMCN1 | c.14200T>C p.Y4734H | Missense Mutation (SNP) | VAF 59/338 reads (17%) | SIFT tolerated (0.57); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- HNRNPUL2 | c.834G>A p.W278* | Nonsense Mutation (SNP) | VAF 161/318 reads (51%) | called by muse, mutect2, varscan2
- HPS5 | c.2617T>C p.S873P (on ENST00000349215 / NM_181507.2; = p.S759P on NM_007216.4) | Missense Mutation (SNP) | VAF 68/336 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- HS3ST4 | c.1264C>A p.P422T | Missense Mutation (SNP) | VAF 73/243 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- HUWE1 | c.8096A>C p.E2699A | Missense Mutation (SNP) | VAF 126/496 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- IGLV5-37 | c.268T>C p.S90P | Missense Mutation (SNP) | VAF 64/330 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- ITGB4 | c.454A>G p.M152V | Missense Mutation (SNP) | VAF 89/230 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- LHX1 | c.779C>T p.P260L | Missense Mutation (SNP) | VAF 76/559 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LRFN5 | c.1184C>A p.S395* | Nonsense Mutation (SNP) | VAF 62/196 reads (32%) | called by muse, mutect2, varscan2
- LRRC53 | c.3233T>C p.I1078T | Missense Mutation (SNP) | VAF 152/314 reads (48%) | SIFT tolerated (0.14); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- LRRN3 | c.1940_1948del p.S647_S650delinsT | In Frame Del (DEL) | VAF 126/446 reads (28%) | called by mutect2, pindel, varscan2
- LZTS1 | c.1384G>A p.E462K | Missense Mutation (SNP) | VAF 120/639 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MAGEC1 | c.2361A>T p.L787F | Missense Mutation (SNP) | VAF 113/503 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.587); called by muse, mutect2, varscan2
- MFHAS1 | c.91C>T p.Q31* | Nonsense Mutation (SNP) | VAF 153/734 reads (21%) | called by muse, mutect2, varscan2
- MID1IP1 | c.448C>A p.H150N | Missense Mutation (SNP) | VAF 297/599 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MORC4 | c.2622G>T p.Q874H | Missense Mutation (SNP) | VAF 167/382 reads (44%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- MROH1 | c.4166A>G p.N1389S | Missense Mutation (SNP) | VAF 136/525 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- NCLN | c.1534_1536del p.Q512del | In Frame Del (DEL) | VAF 71/313 reads (23%) | called by mutect2, pindel, varscan2
- NPHP3 | c.17C>T p.S6L | Missense Mutation (SNP) | VAF 233/344 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- NR2E3 | c.518T>C p.F173S | Missense Mutation (SNP) | VAF 89/442 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- NRIP1 | c.2732A>T p.Y911F | Missense Mutation (SNP) | VAF 59/267 reads (22%) | SIFT tolerated (0.64); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NRXN2 | c.1405_1417del p.A469Tfs*4 | Frame Shift Del (DEL) | VAF 122/331 reads (37%) | called by mutect2, pindel, varscan2
- OLIG2 | c.850_851dup p.F285Afs*105 | Frame Shift Ins (INS) | VAF 156/546 reads (29%) | called by pindel, varscan2
- OR4E2 | c.487A>G p.T163A | Missense Mutation (SNP) | VAF 73/292 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.22); called by muse, mutect2, varscan2
- OSGEP | c.580C>T p.P194S | Missense Mutation (SNP) | VAF 39/232 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PASK | c.1916G>A p.G639E | Missense Mutation (SNP) | VAF 304/463 reads (66%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.826); called by muse, mutect2, varscan2
- PHLDB2 | c.1193T>C p.L398P | Missense Mutation (SNP) | VAF 15/369 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.355); called by muse, mutect2
- PLA2R1 | c.2687A>G p.Y896C | Missense Mutation (SNP) | VAF 12/360 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- PNPLA7 | c.1251G>A p.K417= | Splice Region (SNP) | VAF 51/364 reads (14%) | called by muse, mutect2, varscan2
- PPARGC1B | c.1402A>G p.K468E | Missense Mutation (SNP) | VAF 116/266 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- PREX2 | c.2657G>A p.S886N | Missense Mutation (SNP) | VAF 37/251 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- PSD4 | c.1592A>G p.D531G | Missense Mutation (SNP) | VAF 60/292 reads (21%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- PSMG2 | c.605C>T p.A202V | Missense Mutation (SNP) | VAF 124/260 reads (48%) | SIFT tolerated (0.2); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- PTPRZ1 | c.5339_5342del p.T1780Ifs*24 | Frame Shift Del (DEL) | VAF 86/378 reads (23%) | called by pindel, varscan2
- RIN1 | c.960C>A p.S320R | Missense Mutation (SNP) | VAF 118/663 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- RTL8C | c.149A>G p.Y50C | Missense Mutation (SNP) | VAF 289/711 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- RYR3 | c.8789T>C p.I2930T (on ENST00000389232; = p.I2931T on NM_001036.6) | Missense Mutation (SNP) | VAF 46/273 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.527); called by muse, mutect2, varscan2
- SECISBP2L | c.3079A>T p.T1027S (on ENST00000559471 / NM_001193489.2; = p.T982S on NM_014701.4) | Missense Mutation (SNP) | VAF 71/317 reads (22%) | SIFT tolerated, low confidence (0.19); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- SERPINA2 | c.357C>G p.I119M | Missense Mutation (SNP) | VAF 80/251 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- SERTAD1 | c.407_409del p.A136del | In Frame Del (DEL) | VAF 104/386 reads (27%) | called by mutect2, pindel, varscan2
- SPAG17 | c.2585C>T p.T862I | Missense Mutation (SNP) | VAF 34/203 reads (17%) | SIFT tolerated (0.52); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TCP11X2 | c.1325A>C p.Q442P | Missense Mutation (SNP) | VAF 99/416 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- TOX4 | c.1612T>A p.C538S | Missense Mutation (SNP) | VAF 56/148 reads (38%) | SIFT tolerated (1); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- TRAM2 | c.731+1G>A p.X244_splice | Splice Site (SNP) | VAF 110/254 reads (43%) | called by muse, mutect2, varscan2
- USP34 | c.3487G>C p.V1163L | Missense Mutation (SNP) | VAF 67/286 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- WDR18 | c.324C>T p.V108= | Splice Region (SNP) | VAF 42/243 reads (17%) | called by muse, mutect2, varscan2
- WDR45 | c.521T>A p.L174Q (on ENST00000376372 / NM_001029896.2; = p.L175Q on NM_007075.3) | Missense Mutation (SNP) | VAF 140/308 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- ZBTB38 | c.2805G>T p.R935S | Missense Mutation (SNP) | VAF 85/283 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- ZNF135 | c.242A>C p.Q81P | Missense Mutation (SNP) | VAF 52/185 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- ZNF462 | c.3641A>G p.K1214R | Missense Mutation (SNP) | VAF 74/297 reads (25%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- ZNF629 | c.416T>C p.V139A | Missense Mutation (SNP) | VAF 18/468 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.031); called by muse, mutect2
- ZNF692 | c.10T>C p.S4P | Missense Mutation (SNP) | VAF 85/461 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); called by muse, varscan2
- ZNF76 | c.138G>C p.Q46H | Missense Mutation (SNP) | VAF 65/334 reads (19%) | SIFT tolerated (0.81); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ABCC2 | c.3795C>T p.N1265= | Silent (SNP) | VAF 15/208 reads (7%) | catalogued as rs1270598845; called by muse, mutect2
- AC136428.1 | c.279C>T p.N93= | Silent (SNP) | VAF 54/175 reads (31%) | catalogued as rs1035006412, COSV71169258; called by muse, mutect2, varscan2
- ADGRB1 | c.717G>T p.A239= | Silent (SNP) | VAF 142/708 reads (20%) | called by muse, mutect2, varscan2
- ANXA10 | c.777A>T p.A259= | Silent (SNP) | VAF 50/189 reads (26%) | called by muse, mutect2, varscan2
- AOC2 | c.1722C>T p.S574= | Silent (SNP) | VAF 98/524 reads (19%) | called by muse, mutect2, varscan2
- APOB | c.4911T>C p.N1637= | Silent (SNP) | VAF 84/398 reads (21%) | catalogued as rs776739789; called by muse, mutect2, varscan2
- ARFGEF3 | c.5922C>T p.G1974= | Silent (SNP) | VAF 228/234 reads (97%) | catalogued as rs1294201528; called by muse, mutect2, varscan2
- ATP8A1 | c.2949T>C p.F983= | Silent (SNP) | VAF 61/298 reads (20%) | called by muse, mutect2, varscan2
- BRDT | c.1869T>C p.D623= | Silent (SNP) | VAF 47/233 reads (20%) | called by muse, varscan2
- CACNA1G | c.4141C>A p.R1381= | Silent (SNP) | VAF 88/417 reads (21%) | catalogued as rs536204813; called by muse, mutect2, varscan2
- COL6A3 | c.3588C>T p.T1196= | Silent (SNP) | VAF 107/410 reads (26%) | catalogued as rs1434102843; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DIO2 | c.348C>T p.D116= | Silent (SNP) | VAF 62/242 reads (26%) | called by muse, mutect2, varscan2
- DRGX | c.78C>T p.D26= | Silent (SNP) | VAF 134/134 reads (100%) | catalogued as rs746186282, COSV65136093; called by muse, mutect2, varscan2
- EBF1 | c.1233G>A p.L411= | Silent (SNP) | VAF 110/262 reads (42%) | catalogued as rs940097583; called by muse, mutect2, varscan2
- FANCG | c.555T>C p.S185= | Silent (SNP) | VAF 78/351 reads (22%) | catalogued as COSV100734351; called by muse, mutect2, varscan2
- GRHL1 | c.819C>T p.Y273= | Silent (SNP) | VAF 58/312 reads (19%) | called by muse, mutect2, varscan2
- HSF5 | c.1026T>A p.P342= | Silent (SNP) | VAF 44/216 reads (20%) | called by muse, mutect2, varscan2
- KCNU1 | c.1638C>T p.C546= | Silent (SNP) | VAF 57/336 reads (17%) | called by muse, mutect2, varscan2
- LINGO1 | c.1635C>T p.R545= | Silent (SNP) | VAF 102/551 reads (19%) | catalogued as rs369774840; called by muse, mutect2, varscan2
- MYH8 | c.3375C>T p.I1125= | Silent (SNP) | VAF 147/290 reads (51%) | catalogued as COSV67961904, COSV67967038; called by muse, mutect2, varscan2
- MYLIP | c.1203C>T p.P401= | Silent (SNP) | VAF 59/315 reads (19%) | called by muse, mutect2, varscan2
- OR8K3 | c.360C>T p.Y120= | Silent (SNP) | VAF 187/406 reads (46%) | catalogued as rs540217928, COSV100449783, COSV57131669; called by muse, mutect2, varscan2
- OTOF | c.1641G>A p.T547= | Silent (SNP) | VAF 263/553 reads (48%) | catalogued as rs767607675; called by muse, mutect2, varscan2
- OTUD5 | c.588C>T p.V196= | Silent (SNP) | VAF 133/333 reads (40%) | catalogued as rs372757553; called by muse, mutect2, varscan2
- P2RY8 | c.750C>T p.F250= | Silent (SNP) | VAF 334/685 reads (49%) | catalogued as rs1231627020, COSV67178119; called by muse, mutect2, varscan2
- PCDHGB2 | c.822C>T p.N274= | Silent (SNP) | VAF 187/189 reads (99%) | catalogued as rs990313847; called by muse, mutect2, varscan2
- PDZD2 | c.1755G>A p.S585= | Silent (SNP) | VAF 67/209 reads (32%) | catalogued as rs768229328; called by muse, mutect2, varscan2
- PHF12 | c.915C>T p.L305= | Silent (SNP) | VAF 69/374 reads (18%) | catalogued as rs1337710001; called by muse, mutect2, varscan2
- PPP1R12C | c.138C>T p.T46= | Silent (SNP) | VAF 224/619 reads (36%) | catalogued as rs986555795; called by muse, mutect2, varscan2
- PTCD1 | c.1359C>T p.V453= | Silent (SNP) | VAF 85/721 reads (12%) | called by muse, mutect2, varscan2
- PTPRU | c.4203C>T p.R1401= | Silent (SNP) | VAF 238/495 reads (48%) | called by muse, mutect2, varscan2
- SMG8 | c.2910T>G p.P970= | Silent (SNP) | VAF 155/321 reads (48%) | called by muse, mutect2, varscan2
- STRA6 | c.1461C>T p.N487= | Silent (SNP) | VAF 171/321 reads (53%) | called by muse, mutect2, varscan2
- TLX3 | c.507G>A p.P169= | Silent (SNP) | VAF 299/471 reads (63%) | called by muse, mutect2, varscan2
- TRPC7 | c.1254C>T p.N418= | Silent (SNP) | VAF 139/139 reads (100%) | catalogued as rs377216472, COSV100725735; called by muse, mutect2, varscan2
- XAB2 | c.171C>T p.Y57= | Silent (SNP) | VAF 140/314 reads (45%) | catalogued as rs768566912; called by muse, mutect2, varscan2
- ZMYM6 | c.1389G>A p.K463= | Silent (SNP) | VAF 66/295 reads (22%) | called by muse, mutect2, varscan2
- ZNF556 | c.693C>T p.Y231= | Silent (SNP) | VAF 196/362 reads (54%) | catalogued as rs753596070, COSV56913465; called by muse, mutect2, varscan2
- ZNF830 | c.69G>T p.R23= | Silent (SNP) | VAF 44/326 reads (13%) | called by muse, mutect2, varscan2
- ASAH2 | c.510+2660C>T | Intron (SNP) | VAF 23/269 reads (9%) | catalogued as rs951440701; called by muse, mutect2
- C4orf50 | chr4:5990138 C>T | 5'Flank (SNP) | VAF 82/169 reads (49%) | called by muse, mutect2, varscan2
- PABPC1P4 | n.167A>T | RNA (SNP) | VAF 74/387 reads (19%) | called by muse, mutect2, varscan2
- SIMC1 | c.1678-238T>C | Intron (SNP) | VAF 9/164 reads (5%) | called by muse, mutect2
- ZNF585A | c.*66del | 3'UTR (DEL) | VAF 17/129 reads (13%) | called by mutect2, pindel, varscan2
